Somatic mutation profile of tumor specimen MMRF_1889_2_BM_CD138pos (aliquot MMRF_1889_2_BM_CD138pos_T1_KBS5U_L07241) from MMRF case MMRF_1889, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.3 years (22,773 days).
Specimen MMRF_1889_2_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d55a5ae9-bde0-4ee2-aa97-a3b5a6d50c8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1889_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1889_2_PB_Whole_C3_KBS5U_L07242; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14a7aa30-a7aa-4a8c-b680-5a69fd127bdb

The open-access MAF lists 130 somatic variants for this specimen: 59 protein-altering or splice-affecting, 8 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, 3'UTR 36, Intron 12, Silent 8, 3'Flank 7, 5'Flank 4, RNA 3, Frame Shift Ins 3, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 21/138 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGAP2 | c.2656C>T p.Q886* (on ENST00000547588 / NM_001122772.2; = p.Q530* on NM_014770.4) | Nonsense Mutation (SNP) | VAF 59/301 reads (20%) | catalogued as rs1450649084; called by muse, mutect2, varscan2
- ARHGEF15 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.484); catalogued as rs777849960; called by muse, mutect2, varscan2
- BCO1 | c.1493C>T p.T498M | Missense Mutation (SNP) | VAF 69/73 reads (95%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs375017107; called by muse, mutect2, varscan2
- CHRM1 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs1007009594, COSV61006154; called by muse, mutect2, varscan2
- CTC1 | c.2146C>T p.Q716* | Nonsense Mutation (SNP) | VAF 40/101 reads (40%) | catalogued as COSV59853547; called by muse, mutect2, varscan2
- HMCN1 | c.12964G>T p.D4322Y | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54898028; called by muse, mutect2, varscan2
- IFIT1 | c.1190A>G p.N397S | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs762138107; called by muse, mutect2, varscan2
- IGLL5 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV101597175; called by muse, mutect2
- IGLV3-1 | c.135A>T p.K45N | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs183724895; called by muse, mutect2, varscan2
- INTS13 | c.2071G>C p.E691Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.419); catalogued as rs1431375236, COSV53904462; called by muse, mutect2, varscan2
- KLK15 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56828361; called by muse, mutect2, varscan2
- MAP3K15 | c.2881G>A p.A961T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs765404542, COSV58829723; called by muse, mutect2, varscan2
- MYADM | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 145/306 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs889083260; called by muse, mutect2, varscan2
- NOP16 | c.168G>A p.M56I | Missense Mutation (SNP) | VAF 43/392 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51257680; called by muse, mutect2, varscan2
- NPAP1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 52/433 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.072); catalogued as rs1170974294, COSV61505991; called by muse, mutect2, varscan2
- OCA2 | c.1657G>A p.V553I | Missense Mutation (SNP) | VAF 154/249 reads (62%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.572); catalogued as rs552418165, COSV62339253, COSV62347333; called by muse, mutect2, varscan2
- PAMR1 | c.302dup p.T102Yfs*4 | Frame Shift Ins (INS) | VAF 16/134 reads (12%) | catalogued as rs751755759; called by mutect2, varscan2
- PIK3R5 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777086538, COSV52655561; called by muse, mutect2, varscan2
- REC8 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.719); catalogued as rs774054681; called by muse, mutect2, varscan2
- RNF17 | c.3973A>G p.M1325V | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.166); catalogued as rs868562390; called by muse, mutect2, varscan2
- TRIM42 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53880243, COSV53884442; called by muse, mutect2
- ABCA13 | c.8821C>A p.L2941I | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ACIN1 | c.1592T>C p.L531P | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACTL6B | c.1054A>G p.T352A | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- ADAMTS16 | c.3244T>G p.Y1082D | Missense Mutation (SNP) | VAF 77/123 reads (63%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CACNA1B | c.3259C>T p.P1087S | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CDC40 | c.71G>A p.S24N | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- CDH18 | c.1072T>C p.F358L | Missense Mutation (SNP) | VAF 202/323 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CDH7 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- CGN | c.815G>T p.W272L | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CILP2 | c.1670A>C p.K557T | Missense Mutation (SNP) | VAF 199/304 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- CYFIP2 | c.2293C>A p.P765T (on ENST00000616178 / NM_001291722.2; = p.P740T on NM_014376.4) | Missense Mutation (SNP) | VAF 83/254 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DNAH9 | c.6251C>T p.T2084I | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- EBF2 | c.1051C>A p.Q351K | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); called by muse, mutect2
- EVC2 | c.1914G>T p.M638I | Missense Mutation (SNP) | VAF 95/196 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- IGHV1-69D | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.308); called by muse, varscan2
- INTS9 | c.1046dup p.H349Qfs*6 | Frame Shift Ins (INS) | VAF 77/175 reads (44%) | called by mutect2, pindel, varscan2
- KLHL20 | c.545G>C p.C182S | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- KMT2B | c.5730dup p.R1911Qfs*61 | Frame Shift Ins (INS) | VAF 67/184 reads (36%) | called by mutect2, pindel, varscan2
- LLGL1 | c.3089C>T p.T1030I | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- MAEL | c.1279T>C p.Y427H | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- MON1A | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MTMR8 | c.325C>A p.L109I | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MYH13 | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- OIT3 | c.950A>T p.D317V | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- PLEKHM1 | c.638A>G p.E213G | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRSS36 | c.439T>C p.S147P | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2
- RNF185 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.036); called by muse, mutect2
- RPL23A | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SHISA6 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SLC16A3 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- STEAP4 | c.20A>T p.D7V | Missense Mutation (SNP) | VAF 140/461 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TBX5 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.151); called by muse, mutect2
- TENT5C | c.888del p.F296Lfs*13 | Frame Shift Del (DEL) | VAF 70/202 reads (35%) | called by mutect2, pindel, varscan2
- TTC3 | c.1955G>C p.C652S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VIRMA | c.188C>G p.S63C | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- WNT8B | c.686_694del p.A229_R231del | In Frame Del (DEL) | VAF 9/64 reads (14%) | called by mutect2, pindel*, varscan2
- ZNF169 | c.1804G>C p.V602L | Missense Mutation (SNP) | VAF 127/413 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARSF | c.174C>A p.I58= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs758361610; called by muse, mutect2, varscan2
- CADM2 | c.1174C>T p.L392= (on ENST00000407528 / NM_001167674.2; = p.L394= on NM_153184.4) | Silent (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.225T>C p.D75= | Silent (SNP) | VAF 50/98 reads (51%) | catalogued as rs373801344; called by muse, varscan2
- KXD1 | c.420C>T p.T140= | Silent (SNP) | VAF 14/264 reads (5%) | catalogued as rs1426560462; called by muse, mutect2
- LRP1B | c.2298G>A p.L766= | Silent (SNP) | VAF 10/152 reads (7%) | catalogued as COSV67290452; called by muse, mutect2
- MCM10 | c.117C>T p.P39= | Silent (SNP) | VAF 204/458 reads (45%) | called by muse, mutect2, varscan2
- SOX3 | c.198G>A p.T66= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as rs1038380785; called by muse, mutect2, varscan2
- TNPO3 | c.2454G>C p.R818= | Silent (SNP) | VAF 57/176 reads (32%) | called by muse, mutect2, varscan2
- ABCB9 | c.1743+100T>A | Intron (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- AC020907.6 | chr19:35106379 C>A | 5'Flank (SNP) | VAF 7/19 reads (37%) | called by muse, varscan2
- AC020907.6 | c.-501C>G | 5'UTR (SNP) | VAF 91/357 reads (25%) | called by muse, mutect2, varscan2
- AR | c.*6540G>T | 3'UTR (SNP) | VAF 36/70 reads (51%) | catalogued as rs1449903184; called by muse, mutect2, varscan2
- ARNTL2 | chr12:27421413 C>T | 3'Flank (SNP) | VAF 69/362 reads (19%) | called by muse, varscan2
- ARNTL2 | chr12:27421867 C>T | 3'Flank (SNP) | VAF 24/105 reads (23%) | called by muse, varscan2
- ARNTL2 | chr12:27422085 C>T | 3'Flank (SNP) | VAF 13/120 reads (11%) | called by muse, mutect2, varscan2
- ARPC4 | c.*916G>A | 3'UTR (SNP) | VAF 25/40 reads (63%) | called by muse, mutect2, varscan2
- ASF1B | c.*290_*292dup | 3'UTR (INS) | VAF 61/200 reads (31%) | called by mutect2, pindel, varscan2
- C15orf54 | n.427C>T | RNA (SNP) | VAF 38/113 reads (34%) | catalogued as rs770581044; called by muse, mutect2, varscan2
- CCNYL2 | n.624-2485C>A | Intron (SNP) | VAF 72/163 reads (44%) | called by muse, mutect2, varscan2
- CD96 | c.*2364A>G | 3'UTR (SNP) | VAF 8/135 reads (6%) | called by muse, mutect2
- CGNL1 | c.*215G>A | 3'UTR (SNP) | VAF 19/134 reads (14%) | catalogued as rs1282126239; called by muse, mutect2, varscan2
- CRYBG1 | c.*874C>A | 3'UTR (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- CTNND2 | c.*647C>T | 3'UTR (SNP) | VAF 39/128 reads (30%) | called by muse, mutect2, varscan2
- DGKB | c.1287+25T>C | Intron (SNP) | VAF 142/214 reads (66%) | called by muse, mutect2, varscan2
- EOMES | c.*600T>G | 3'UTR (SNP) | VAF 42/78 reads (54%) | called by muse, mutect2, varscan2
- EVI5 | c.*2505del | 3'UTR (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- EVI5 | c.*2504T>A | 3'UTR (SNP) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- FBXL21P | n.1540T>C | RNA (SNP) | VAF 37/139 reads (27%) | called by muse, mutect2, varscan2
- GALNT17 | c.*1162G>A | 3'UTR (SNP) | VAF 12/197 reads (6%) | called by muse, mutect2
- GBP2 | c.429-26G>A | Intron (SNP) | VAF 32/61 reads (52%) | called by muse, mutect2, varscan2
- GLI3 | c.*1469C>T | 3'UTR (SNP) | VAF 67/197 reads (34%) | called by muse, mutect2, varscan2
- GLRB | c.*1186C>T | 3'UTR (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- GNB5 | c.494+274T>A | Intron (SNP) | VAF 6/74 reads (8%) | catalogued as rs1221020842; called by muse, mutect2
- GNG7 | c.-78+3328C>A | Intron (SNP) | VAF 163/259 reads (63%) | catalogued as COSV66284558; called by muse, mutect2, varscan2
- GYPA | c.37+2428T>G | Intron (SNP) | VAF 134/277 reads (48%) | called by muse, mutect2, varscan2
- HS3ST1 | c.*3349G>C | 3'UTR (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- INSM1 | c.*131T>A | 3'UTR (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2, varscan2
- INTS13 | c.*51G>T | 3'UTR (SNP) | VAF 89/266 reads (33%) | called by muse, mutect2, varscan2
- KIF26A | chr14:104180608 G>A | 3'Flank (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- LIG3 | c.*4627T>C | 3'UTR (SNP) | VAF 65/145 reads (45%) | called by muse, mutect2, varscan2
- LPAR1 | chr9:110873345 T>A | 3'Flank (SNP) | VAF 14/133 reads (11%) | called by muse, mutect2, varscan2
- LPGAT1 | c.*5807C>T | 3'UTR (SNP) | VAF 43/70 reads (61%) | catalogued as rs185842209; called by muse, mutect2, varscan2
- LRATD1 | c.*3918C>G | 3'UTR (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
- MAPK10 | c.*558G>T | 3'UTR (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- MECP2 | c.*6575G>A | 3'UTR (SNP) | VAF 82/213 reads (38%) | catalogued as rs1275523085; called by muse, mutect2, varscan2
- MED28 | c.*8254T>A | 3'UTR (SNP) | VAF 5/26 reads (19%) | called by muse, varscan2
- MIP | c.*1230T>G | 3'UTR (SNP) | VAF 24/56 reads (43%) | catalogued as rs1440665212; called by muse, mutect2, varscan2
- NCOR1 | c.6679+1981A>T | Intron (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- NRXN3 | chr14:79864197 C>G | 3'Flank (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- OR10AG1 | c.*4G>T | 3'UTR (SNP) | VAF 15/396 reads (4%) | catalogued as rs1044942608; called by muse, mutect2
- PAPOLB | c.*211G>A | 3'UTR (SNP) | VAF 60/158 reads (38%) | catalogued as rs925964155; called by muse, mutect2, varscan2
- PBX2P1 | n.129dup | RNA (INS) | VAF 18/52 reads (35%) | catalogued as rs1200067574; called by mutect2, pindel, varscan2
- PHACTR2 | c.*3463G>A | 3'UTR (SNP) | VAF 5/34 reads (15%) | catalogued as rs867222117; called by muse, varscan2
- PI15 | c.*4778T>G | 3'UTR (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- PLD1 | c.*1758T>A | 3'UTR (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- PYGO1 | c.*6082C>G | 3'UTR (SNP) | VAF 57/189 reads (30%) | called by muse, mutect2, varscan2
- RARB | c.179-32872A>C | Intron (SNP) | VAF 46/110 reads (42%) | called by muse, mutect2, varscan2
- RNF125 | c.*3969A>T | 3'UTR (SNP) | VAF 50/95 reads (53%) | called by muse, mutect2, varscan2
- RNU6-1191P | chr16:81109414 C>A | 5'Flank (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- RUNX1 | c.724+13043C>T | Intron (SNP) | VAF 38/154 reads (25%) | called by muse, mutect2, varscan2
- SEC63 | c.*2815T>G | 3'UTR (SNP) | VAF 40/75 reads (53%) | called by muse, mutect2, varscan2
- SEC63 | c.*2012T>A | 3'UTR (SNP) | VAF 49/110 reads (45%) | called by muse, mutect2, varscan2
- SF1 | c.*1054C>T | 3'UTR (SNP) | VAF 26/59 reads (44%) | catalogued as rs1220723830; called by muse, mutect2, varscan2
- SIX1 | chr14:60652554 C>T | 5'Flank (SNP) | VAF 22/119 reads (18%) | called by muse, mutect2, varscan2
- SLC1A6 | chr19:14972921 C>T | 5'Flank (SNP) | VAF 7/33 reads (21%) | catalogued as rs1319458140; called by muse, mutect2
- SMIM19 | chr8:42552984 C>G | 3'Flank (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- TDRD1 | c.*38T>A | 3'UTR (SNP) | VAF 260/558 reads (47%) | called by muse, mutect2, varscan2
- TIFA | c.*769T>A | 3'UTR (SNP) | VAF 48/100 reads (48%) | called by muse, mutect2, varscan2
- VCL | c.783+2766C>T | Intron (SNP) | VAF 105/245 reads (43%) | called by muse, mutect2, varscan2
- VPS13C | c.*421C>T | 3'UTR (SNP) | VAF 9/28 reads (32%) | catalogued as rs1394694122; called by muse, mutect2
- ZC3H12C | c.22-27T>C | Intron (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
